Somatic mutation profile of tumor specimen TCGA-GC-A3RD-01A (aliquot TCGA-GC-A3RD-01A-12D-A22Z-08) from TCGA case TCGA-GC-A3RD, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Trigone of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 83.6 years (30,529 days).
Specimen TCGA-GC-A3RD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a68a5fca-43a1-43b8-9240-83248fcaa834.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GC-A3RD-10B (Blood Derived Normal), aliquot TCGA-GC-A3RD-10B-01D-A22Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/05e6d4e9-f644-46ae-9e08-55f8f23c9e64

The open-access MAF lists 95 somatic variants for this specimen: 65 protein-altering or splice-affecting, 29 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 29, Nonsense Mutation 6, Frame Shift Del 3, Frame Shift Ins 3, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC8 | c.2318C>T p.S773L | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); catalogued as rs1355146733, COSV56846265; called by muse, mutect2, varscan2
- ADGRV1 | c.1042G>A p.D348N | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV67978501; called by muse, mutect2, varscan2
- APLP1 | c.1581G>A p.G527= (on ENST00000221891 / NM_001024807.3; = p.G526= on NM_005166.4) | Splice Region (SNP) | VAF 9/37 reads (24%) | catalogued as COSV55701663; called by muse, mutect2, varscan2
- ARSD | c.1618G>A p.V540M | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as rs757945599, COSV66972821; called by muse, mutect2, varscan2
- ASXL1 | c.3835G>A p.V1279M | Missense Mutation (SNP) | VAF 36/62 reads (58%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.192); catalogued as COSV60103164; called by muse, mutect2, varscan2
- BNC1 | c.937A>G p.K313E | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV61756499, COSV61757336; called by muse, mutect2, varscan2
- CA10 | c.816G>T p.Q272H | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs149523462; called by muse, varscan2
- CELSR1 | c.7847C>T p.A2616V | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.537); catalogued as rs62226999, COSV53083502; called by muse, mutect2, varscan2
- COL1A2 | c.1573G>A p.D525N | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.836); catalogued as COSV51952908; called by muse, mutect2, varscan2
- DCUN1D2 | c.5A>G p.H2R | Missense Mutation (SNP) | VAF 59/72 reads (82%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as COSV60260673; called by muse, mutect2, varscan2
- DDX4 | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs374972771; called by muse, mutect2, varscan2
- DMD | c.6323G>A p.R2108H | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs1291065884, COSV63735186; called by muse, mutect2, varscan2
- DTX4 | c.1415G>C p.G472A | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1352012145, COSV57088225; called by muse, mutect2, varscan2
- EFCAB5 | c.437dup p.A147Gfs*2 | Frame Shift Ins (INS) | VAF 6/12 reads (50%) | catalogued as rs767553068; called by mutect2, varscan2
- FAM214A | c.217C>T p.R73* | Nonsense Mutation (SNP) | VAF 14/60 reads (23%) | catalogued as COSV55927055; called by muse, mutect2, varscan2
- FAT3 | c.3283G>A p.D1095N | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.108); catalogued as rs774427780, COSV53075705; called by muse, mutect2, varscan2
- FBXW7 | c.1925A>G p.D642G (on ENST00000281708 / NM_001349798.2; = p.D562G on NM_018315.5) | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55893782; called by muse, mutect2, varscan2
- FCGBP | c.8228C>T p.A2743V | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.041); catalogued as rs372938963; called by mutect2, varscan2
- GPR21 | c.730G>A p.A244T | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV65378804; called by muse, mutect2, varscan2
- H2BC17 | c.227_237del p.G76Afs*? | Frame Shift Del (DEL) | VAF 35/102 reads (34%) | catalogued as COSV58151979; called by mutect2, pindel, varscan2
- IGF2R | c.5581_5588del p.T1861Gfs*18 | Frame Shift Del (DEL) | VAF 7/27 reads (26%) | catalogued as COSV63626397; called by mutect2, pindel, varscan2
- IGKV3-11 | c.331C>A p.R111S | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs373816363; called by muse, mutect2, varscan2
- ITGA3 | c.1066C>T p.H356Y | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.187); catalogued as COSV50306017; called by muse, mutect2, varscan2
- IZUMO1R | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.083); catalogued as COSV60622147; called by muse, mutect2, varscan2
- KDM4A | c.1651G>C p.D551H | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.266); catalogued as COSV64958803; called by muse, mutect2, varscan2
- KMT2D | c.6935C>T p.S2312L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs949690934, COSV56410740, COSV56412606; called by muse, mutect2, varscan2
- MRAP | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57936326; called by muse, mutect2, varscan2
- NKPD1 | c.828C>A p.F276L | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV58727833; called by muse, mutect2, varscan2
- PCDHA5 | c.1435C>T p.R479W | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.045); catalogued as rs782665262, COSV65349338; called by muse, mutect2, varscan2
- PCDHA9 | c.2045C>T p.A682V | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV65323372; called by muse, mutect2, varscan2
- PCK1 | c.538G>A p.V180I | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.346); catalogued as rs367998997; ClinVar: uncertain significance; called by muse, mutect2
- PPFIA4 | c.1877C>A p.S626Y (on ENST00000447715; = p.S627Y on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as COSV55311334; called by muse, mutect2, varscan2
- PSMC2 | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV53006538; called by muse, varscan2
- PSMC2 | c.1106G>A p.R369K | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as COSV53006551; called by muse, varscan2
- PSMC2 | c.1147G>A p.A383T | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53006564; called by muse, varscan2
- RBM26 | c.1924C>G p.P642A (on ENST00000438737 / NM_001366735.2; = p.P639A on NM_022118.5) | Missense Mutation (SNP) | VAF 37/46 reads (80%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.543); catalogued as COSV57391241; called by muse, mutect2, varscan2
- SAE1 | c.163C>T p.L55F | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV54293179; called by muse, mutect2, varscan2
- SCAPER | c.2423T>A p.F808Y | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV57733987; called by muse, mutect2, varscan2
- SCNN1D | c.611G>C p.R204T (on ENST00000338555; = p.R368T on NM_001130413.4) | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.16); catalogued as rs1436040833, COSV57639869; called by muse, mutect2, varscan2
- SLC17A3 | c.378C>A p.S126R | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV57759429; called by muse, mutect2, varscan2
- SP4 | c.701G>C p.R234T | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.95); catalogued as COSV56020774; called by muse, mutect2, varscan2
- SPATA13 | c.1271G>A p.R424H | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs777744409, COSV57976058; called by mutect2, varscan2
- STIL | c.3048G>C p.K1016N | Missense Mutation (SNP) | VAF 43/53 reads (81%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as COSV54547633; called by muse, mutect2, varscan2
- THNSL1 | c.2151G>C p.K717N | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV64478948, COSV64479776; called by muse, mutect2, varscan2
- TLL2 | c.2354G>A p.G785E | Missense Mutation (SNP) | VAF 39/56 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63570719; called by muse, mutect2, varscan2
- TMEM200A | c.518T>C p.L173P | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV51649169, COSV51659385; called by muse, mutect2, varscan2
- TRIP10 | c.1436G>T p.R479L (on ENST00000313244 / NM_001288962.2; = p.R423L on NM_004240.4) | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV55584635; called by muse, mutect2, varscan2
- TRMT61B | c.1264C>G p.Q422E | Missense Mutation (SNP) | VAF 27/33 reads (82%) | SIFT tolerated (0.43); PolyPhen benign (0.011); catalogued as COSV60257474; called by muse, mutect2, varscan2
- UBE2N | c.447G>A p.M149I | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV58866859; called by muse, mutect2, varscan2
- UGT2A3 | c.787G>C p.E263Q | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.39); catalogued as COSV52358813, COSV52362425; called by muse, mutect2, varscan2
- VSTM1 | c.680G>T p.G227V | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as COSV58073864, COSV58073959; called by muse, mutect2, varscan2
- WFIKKN2 | c.1253G>A p.G418D | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60957816; called by muse, mutect2, varscan2
- ZFP37 | c.532G>C p.E178Q | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV65285839; called by muse, mutect2, varscan2
- ZNF92 | c.1159C>T p.H387Y (on ENST00000328747 / NM_152626.4; = p.H318Y on NM_007139.4) | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774200428, COSV60873020; called by muse, mutect2, varscan2
- ZZEF1 | c.4040G>A p.R1347H | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs755516543, COSV67555943; called by muse, mutect2, varscan2
- ACTL6B | c.295dup p.I99Nfs*13 | Frame Shift Ins (INS) | VAF 10/41 reads (24%) | called by mutect2, pindel, varscan2
- ADGRV1 | c.820G>T p.E274* | Nonsense Mutation (SNP) | VAF 15/87 reads (17%) | called by muse, mutect2, varscan2
- ANK2 | c.10393G>T p.E3465* | Nonsense Mutation (SNP) | VAF 14/52 reads (27%) | called by muse, mutect2, varscan2
- CREBBP | c.2040dup p.N681Efs*45 | Frame Shift Ins (INS) | VAF 32/141 reads (23%) | called by mutect2, pindel, varscan2
- GRIA4 | c.1774G>T p.E592* | Nonsense Mutation (SNP) | VAF 9/24 reads (38%) | called by muse, mutect2, varscan2
- IGKV1D-16 | c.8T>A p.M3K | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- KHDRBS2 | c.265A>T p.K89* | Nonsense Mutation (SNP) | VAF 21/59 reads (36%) | called by muse, mutect2, varscan2
- OR2M3 | c.4del p.A2? | Frame Shift Del (DEL) | VAF 39/190 reads (21%) | called by mutect2, pindel, varscan2
- SEMA3A | c.1894C>G p.Q632E | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.15); called by muse, mutect2
- ZNF615 | c.283C>T p.Q95* | Nonsense Mutation (SNP) | VAF 22/43 reads (51%) | called by muse, mutect2, varscan2
- ACTN4 | c.387C>T p.I129= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as rs550083317, COSV53142952; called by muse, mutect2, varscan2
- ATP2B2 | c.1248G>A p.P416= (on ENST00000352432; = p.P382= on NM_001683.5) | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as rs113465029, COSV59489108; called by muse, mutect2, varscan2
- ATP8B4 | c.3075C>T p.I1025= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as rs756577155, COSV52709200; called by muse, mutect2, varscan2
- ATP8B4 | c.2679C>T p.F893= | Silent (SNP) | VAF 27/110 reads (25%) | catalogued as COSV52709207; called by muse, mutect2, varscan2
- B3GAT2 | c.288G>A p.A96= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV57768750; called by muse, mutect2
- C7orf26 | c.513C>T p.F171= | Silent (SNP) | VAF 11/147 reads (7%) | catalogued as COSV60417901; called by muse, mutect2
- CLEC11A | c.807C>T p.R269= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as COSV51573497; called by muse, mutect2, varscan2
- COL18A1 | c.78G>C p.L26= | Silent (SNP) | VAF 21/116 reads (18%) | catalogued as COSV62698577; called by muse, mutect2, varscan2
- DSCAM | c.4410C>A p.T1470= | Silent (SNP) | VAF 8/110 reads (7%) | called by muse, mutect2
- FBN1 | c.228C>A p.G76= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as rs141651917, COSV57309315; called by muse, mutect2, varscan2
- HOMER2 | c.318G>T p.V106= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV58484383; called by muse, mutect2, varscan2
- IRX5 | c.615G>A p.Q205= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV58058379; called by muse, mutect2, varscan2
- KCNA6 | c.834C>T p.L278= | Silent (SNP) | VAF 25/100 reads (25%) | catalogued as COSV54974017; called by muse, mutect2, varscan2
- KIAA1210 | c.1701C>T p.G567= | Silent (SNP) | VAF 28/78 reads (36%) | catalogued as rs758145611, COSV68175445; called by muse, mutect2, varscan2
- MMP26 | c.48C>T p.F16= | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as rs757679480, COSV56171254; called by muse, mutect2, varscan2
- NKPD1 | c.1419C>G p.L473= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as COSV58727816; called by muse, mutect2
- OR51S1 | c.493C>T p.L165= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV59057240; called by muse, mutect2
- PAPPA | c.2049C>A p.G683= | Silent (SNP) | VAF 40/106 reads (38%) | catalogued as COSV60277488; called by muse, mutect2, varscan2
- PCNT | c.7428C>T p.L2476= | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as COSV64025028; called by muse, mutect2, varscan2
- PHF20 | c.33C>T p.I11= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV59184493; called by muse, mutect2, varscan2
- PLEKHH2 | c.1035A>G p.R345= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV56749709; called by muse, mutect2, varscan2
- PLEKHM2 | c.1137G>A p.P379= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV65395157; called by muse, mutect2, varscan2
- PSAP | c.657C>T p.V219= | Silent (SNP) | VAF 5/56 reads (9%) | catalogued as COSV67549712; called by muse, mutect2
- PSMC2 | c.906G>C p.L302= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as COSV53006509; called by muse, varscan2
- RBFOX2 | c.1305C>T p.G435= (on ENST00000438146 / NM_001349995.2; = p.A348V on NM_014309.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/345 reads (7%) | catalogued as rs749041051, COSV53262804; called by muse, mutect2
- RPS8 | c.159G>A p.K53= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV63234316; called by muse, mutect2, varscan2
- SQSTM1 | c.1282C>T p.L428= | Silent (SNP) | VAF 29/103 reads (28%) | catalogued as COSV52971761; called by muse, mutect2, varscan2
- UNC80 | c.744C>A p.I248= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as COSV55883580; called by muse, mutect2, varscan2
- ZC3H12C | c.1392G>A p.L464= | Silent (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
- AC024598.1 | c.1130-1028C>T | Intron (SNP) | VAF 8/24 reads (33%) | catalogued as COSV100760463, COSV60823681; called by muse, mutect2, varscan2
